Surgical pathology report (de-identified scan), TCGA case TCGA-KR-A7K0, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University Of Michigan, specimen TCGA-KR-A7K0-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #: 10

BIRTHDATE:

SEX: M
ADM DATE:

*ICC-D-3
Carcinoma, hepatocellular
8/70/13
Sub Liver NOS
C22.0
JW 8/27/13*

OPER DATE:

PROCEDURE: SPHS

Liver cancer. Operative Procedure/Tissue Submitted: Laparoscopic assisted liver resection.

PROCEDURE: SPGD

1. "Gallbladder." Received in formalin in a medium container is a previously disrupted 11.8 x 4.6 x 1.6 cm gallbladder with focally adhered serosa. The lumen is devoid of content. The mucosa is red-tan, velvety with a 0.2 cm average wall thickness. The cystic duct is patent and there are no separate stones in the container.

1A. Gallbladder.

2. "Segment 5-6 liver resection, gross margins." A 5.5 x 5.0 x 4.8 cm, 65 gm resection of liver with nodular capsular surface. The margin is inked black. A 2.1 cm nodule is 1.9 cm from the margin. The nodular mass comes to within 0.1 cm of the capsule. The remaining parenchyma has multiple nodules that average 0.4 cm in greatest dimension. The diffuse nodular parenchyma is focally fibrous.

2A-D. Mass with nodular parenchyma and surgical margin.

INTRAOPERATIVE GROSS:

=====

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #: 11

BIRTHDATE:

SEX: M

ADM DATE:

OPER DATE:

2. A 2.1 cm nodule is 1.9 cm from margin.

PROCEDURE: SPMI

VERIFIED BY:

LIVER: HEPATOCELLULAR CARCINOMA

=====

WAS THE TUMOR PREVIOUSLY TREATED?: No

TUMOR TYPE: Ordinary

SINGLE OR MULTIPLE MASSES: Single

MAXIMUM DIAMETER OF LARGEST MASS: 2.1 cm

ARE THE MARGINS OF RESECTION FREE OF TUMOR?: Yes

VASCULAR INVASION?: No

INVASION THROUGH THE CAPSULE TO THE SEROSAL SURFACE?: No

LYMPH NODE METASTASES?: Unknown

DISTANT METASTASES?: Unknown

IS THE LIVER CIRRHOTIC?: Yes, cryptogenic
pT1 NX

PROCEDURE: SPDY

1. Gallbladder, resection: No significant abnormality.

2. Liver, segments 5 and 6, resection: Well-differentiated hepatocellular carcinoma (2.1cm). Margins negative. Cryptogenic cirrhosis. Please see TEMPLATE for details.

Source: NCI Genomic Data Commons file 94f8ddc5-e86d-4032-81e5-bafd04083b36 (TCGA-KR-A7K0.34BFDBBD-A66F-4436-AD51-D6AA979F2CD3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).